Somatic mutation profile of tumor specimen TCGA-DJ-A3V6-01A (aliquot TCGA-DJ-A3V6-01A-11D-A22Z-08) from TCGA case TCGA-DJ-A3V6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 54.4 years (19,870 days).
Specimen TCGA-DJ-A3V6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fd6d4d3-21f5-49e3-8dca-530493e2274b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V6-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V6-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e6c91dc-c6d3-46de-ab8b-a4c7424ac8ce

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KCNA1 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 157/419 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs104894355, CM981109, COSV66837628; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNC3 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65388386; called by mutect2, varscan2
- LRP10 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377217522; called by muse, mutect2, varscan2
- PCDH1 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99745902; called by muse, mutect2, varscan2
- PLEC | c.1877A>T p.N626I (on ENST00000322810 / NM_201380.4; = p.N516I on NM_000445.5) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100512715; called by muse, mutect2, varscan2
- PLSCR4 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs777508138, COSV100724354, COSV61608458; called by muse, mutect2, varscan2
- PRCP | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV100475844; called by muse, mutect2, varscan2
- TECR | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs773934673, COSV99295055; called by muse, mutect2, varscan2
- ZNF644 | c.3485G>T p.S1162I | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100494370; called by muse, mutect2
- ERBIN | c.545G>T p.R182I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- ADD3 | c.183C>T p.I61= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs376781474; called by muse, mutect2, varscan2
- DSPP | c.1062C>T p.R354= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs751979983, COSV99217030; called by muse, mutect2, varscan2
- ESYT3 | c.2037C>T p.I679= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs368985977; called by muse, mutect2, varscan2
- M1AP | c.834C>T p.D278= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs745433133, COSV51849861; called by muse, mutect2, varscan2
- OR51T1 | c.150C>T p.V50= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV100434365; called by muse, mutect2, varscan2
